Gene-level copy-number profile of tumor specimen TCGA-HT-A614-01A from TCGA case TCGA-HT-A614, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.6 years (17,392 days).
Specimen TCGA-HT-A614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.a8dbbb00-21a9-495c-9fb3-2397d93c1a50.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A614-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/feb2e4a0-1662-4ac4-a714-215fafcaec42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,866; copy number 2: 53,265; copy number 3: 1,291; copy number 6: 393; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A614-01A-11D-A323-01): tumor purity 0.81, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 394 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:3,871,579–13,387,167, 392 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).
- chr12:13,440,884–13,459,776, 2 genes, copy number 6: RNA5SP353, RNU6-590P.

Autosomal genes at a single copy (total copy number 1): 2,479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
